Somatic mutation profile of tumor specimen TCGA-DD-AADO-01A (aliquot TCGA-DD-AADO-01A-11D-A40R-10) from TCGA case TCGA-DD-AADO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.1 years (20,139 days).
Specimen TCGA-DD-AADO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5a12eac-0ad8-4213-9091-26a882fca0d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADO-10A (Blood Derived Normal), aliquot TCGA-DD-AADO-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8de8909-3344-4fb0-b63d-48ab5410ffc7

The open-access MAF lists 238 somatic variants for this specimen: 177 protein-altering or splice-affecting, 58 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 58, Nonsense Mutation 11, Frame Shift Del 5, Frame Shift Ins 2, In Frame Del 2, RNA 2, Splice Region 1, Translation Start Site 1, Splice Site 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs77375493, CM123094, COSV67569051, COSV67571909; ClinVar: risk factor / pathogenic / likely pathogenic / not provided / affects; called by muse, mutect2, varscan2
- RYR1 | c.14677C>T p.R4893W | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs118192150, CM013432, COSV100616914; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD10 | c.662T>A p.F221Y | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99845188; called by muse, mutect2, varscan2
- AC008397.2 | c.1349T>C p.M450T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99442257; called by muse, mutect2, varscan2
- AC013489.1 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV99183896; called by muse, mutect2
- ADARB2 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.338); catalogued as COSV101187274; called by muse, mutect2, varscan2
- AKAP9 | c.9918G>T p.M3306I (on ENST00000359028; = p.M3282I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as COSV100663060; called by muse, mutect2, varscan2
- ANGPT1 | c.1149C>G p.N383K | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV104399210, COSV99864101; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7072G>T p.A2358S | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.003); catalogued as rs750965639, COSV99784408; called by muse, mutect2, varscan2
- ARHGAP35 | c.1378A>G p.M460V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV101351670; called by muse, mutect2, varscan2
- ARHGEF15 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100730231, COSV62724826; called by muse, mutect2, varscan2
- ASB13 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.268); catalogued as COSV100731419; called by muse, mutect2, varscan2
- ASB2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1433633018, COSV100279583; called by muse, mutect2, varscan2
- ASB4 | c.205T>C p.Y69H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99987230; called by muse, mutect2, varscan2
- ATP13A5 | c.3490C>G p.L1164V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as COSV99290984; called by muse, mutect2, varscan2
- AXIN1 | c.1481del p.P494Rfs*211 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as COSV51993579; called by mutect2, pindel, varscan2
- BLM | c.536G>T p.R179I | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100757329; called by muse, mutect2, varscan2
- CABP4 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100351661; called by muse, mutect2, varscan2
- CADPS2 | c.3545T>A p.V1182D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100465784; called by muse, mutect2, varscan2
- CASR | c.1582T>C p.F528L (on ENST00000490131; = p.F605L on NM_000388.4) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99949457; called by muse, mutect2
- CCDC6 | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99569831; called by muse, mutect2, varscan2
- CCDC80 | c.1408A>G p.R470G | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV99245269; called by muse, mutect2, varscan2
- CCND1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1271260640, COSV99919817; called by mutect2, varscan2
- CDHR2 | c.3781C>G p.Q1261E | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99991008, COSV99992161; called by muse, mutect2, varscan2
- CENPF | c.2434A>C p.S812R | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.281); catalogued as COSV100871960; called by muse, mutect2, varscan2
- CETN2 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV64744399; called by muse, mutect2, varscan2
- CHM | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100753619; called by muse, mutect2, varscan2
- CLK4 | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100309105; called by muse, mutect2, varscan2
- COL12A1 | c.5695A>T p.I1899F | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV100486459; called by muse, mutect2, varscan2
- COL24A1 | c.3789A>G p.E1263= | Splice Region (SNP) | VAF 31/126 reads (25%) | catalogued as COSV100993960; called by muse, mutect2, varscan2
- COL28A1 | c.334A>C p.K112Q | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.13); catalogued as COSV101258927; called by muse, mutect2, varscan2
- COMMD8 | c.53A>T p.E18V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV101055779; called by muse, mutect2, varscan2
- COMP | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1374391457, COSV99721574; called by muse, mutect2, varscan2
- CTSH | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs941033377, COSV99585665; called by muse, mutect2, varscan2
- CYP17A1 | c.363G>A p.W121* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100882141; called by muse, mutect2, varscan2
- DMBT1 | c.3197A>G p.E1066G (on ENST00000338354 / NM_001377530.1; = p.E567G on NM_004406.3) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100354050; called by muse, mutect2, varscan2
- DNAH7 | c.4012A>T p.T1338S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV100417456; called by muse, mutect2, varscan2
- DOCK10 | c.5699A>T p.E1900V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99291528; called by muse, mutect2, varscan2
- DOCK10 | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV99291531; called by muse, mutect2, varscan2
- DOCK5 | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV99377816; called by muse, mutect2, varscan2
- DPYD | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV64593381; called by muse, mutect2, varscan2
- DST | c.20647A>G p.I6883V (on ENST00000361203 / NM_001374722.1; = p.I4580V on NM_015548.5) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.084); catalogued as rs752769638, COSV99759749; called by muse, mutect2, varscan2
- DYRK1A | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100118290; called by muse, mutect2, varscan2
- EBAG9 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as COSV100520908; called by muse, mutect2, varscan2
- ENDOV | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100108644; called by muse, mutect2
- EPHX1 | c.949T>A p.S317T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99689202; called by muse, mutect2, varscan2
- ERC2 | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV99889609; called by muse, mutect2, varscan2
- FAM126A | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.271); catalogued as COSV101327261; called by muse, mutect2, varscan2
- FAM13A | c.1475A>C p.N492T | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99984641; called by muse, mutect2, varscan2
- FASN | c.4064A>T p.D1355V | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100148306; called by muse, mutect2, varscan2
- FERMT1 | c.56A>G p.D19G | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.187); catalogued as rs1372798358, COSV99452113; called by muse, mutect2, varscan2
- FLG | c.6446G>A p.R2149K | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs1161861110, COSV100912168; called by muse, mutect2, varscan2
- FOXI1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100089278, COSV60390469; called by muse, mutect2, varscan2
- FOXN4 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV100142293; called by muse, mutect2
- FSTL5 | c.2296G>A p.V766M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100060759; called by muse, mutect2, varscan2
- GAB4 | c.358A>G p.M120V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101272102; called by muse, mutect2, varscan2
- GAD2 | c.620A>T p.Y207F | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs771522366, COSV52157893, COSV99393989; called by muse, mutect2, varscan2
- GALNT3 | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV101205010; called by muse, mutect2, varscan2
- GLS | c.1754A>T p.D585V | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57845680; called by muse, mutect2, varscan2
- GMFG | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99453501; called by muse, mutect2, varscan2
- GOLGA1 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101002597; called by muse, mutect2, varscan2
- GRM8 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100285877; called by muse, mutect2, varscan2
- HOXA3 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100415683; called by muse, mutect2, varscan2
- HUNK | c.1639A>T p.I547F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.024); catalogued as COSV99528936; called by muse, mutect2, varscan2
- ID1 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV101076835; called by muse, mutect2, varscan2
- ITPR3 | c.5044C>T p.R1682W | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs748669362, COSV100968099; called by muse, mutect2
- KCTD16 | c.991G>T p.G331C | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV101568884; called by muse, mutect2, varscan2
- KIAA2026 | c.5143A>G p.T1715A | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV101199197; called by muse, mutect2
- KIF21A | c.947A>T p.K316M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100735638; called by muse, mutect2, varscan2
- KRTAP10-9 | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV100555405; called by muse, mutect2, varscan2
- LAMA1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.87); catalogued as rs375547281; called by muse, mutect2, varscan2
- LAMB2 | c.2803A>G p.S935G | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100026479; called by muse, mutect2, varscan2
- MCF2L | c.835G>A p.D279N (on ENST00000375608; = p.D247N on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV100982945; called by muse, mutect2, varscan2
- MFGE8 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs148213281; called by muse, mutect2, varscan2
- MGAT4A | c.1551G>T p.Q517H | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99384686; called by muse, mutect2, varscan2
- MKLN1 | c.873G>A p.W291* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as COSV100760003; called by muse, mutect2, varscan2
- MME | c.1642T>A p.S548T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100852534; called by muse, mutect2, varscan2
- MSL2 | c.1711A>G p.I571V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs1277309986, COSV53860037; called by muse, mutect2, varscan2
- MUC16 | c.10694A>T p.D3565V | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); catalogued as COSV101201526; called by muse, mutect2, varscan2
- MYCT1 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV100924092; called by muse, mutect2, varscan2
- MYO6 | c.2542A>G p.K848E | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV100889415; called by muse, mutect2, varscan2
- MYOC | c.1418A>T p.Y473F | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231714; called by muse, mutect2
- N4BP1 | c.2690G>T p.*897Lext*4 | Nonstop Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as COSV99285560; called by muse, mutect2, varscan2
- NBAS | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99871521; called by muse, mutect2
- NBN | c.37G>T p.G13* | Nonsense Mutation (SNP) | VAF 68/567 reads (12%) | catalogued as COSV99620066; called by muse, mutect2, varscan2
- NCAM2 | c.2343T>A p.N781K | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99525141; called by muse, mutect2, varscan2
- NDEL1 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV100233254; called by muse, mutect2
- NIBAN1 | c.2234A>T p.E745V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV100836613; called by muse, mutect2, varscan2
- NOS1 | c.640A>G p.S214G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100501372; called by muse, mutect2, varscan2
- NR1I2 | c.339G>C p.M113I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV100561711; called by muse, mutect2, varscan2
- NR1I2 | c.340T>A p.S114T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.772); catalogued as COSV100561712; called by muse, varscan2
- NRXN1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as rs369183287, COSV68037438; called by muse, mutect2, varscan2
- NT5C1B | c.1014T>A p.Y338* (on ENST00000359846 / NM_001199086.2; = p.Y278* on NM_033253.4) | Nonsense Mutation (SNP) | VAF 27/176 reads (15%) | catalogued as COSV100410279; called by muse, mutect2, varscan2
- NTRK1 | c.2311C>T p.R771C | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324983370, COSV100693757; called by muse, mutect2, varscan2
- NUMB | c.760G>T p.E254* (on ENST00000355058; = p.E243* on NM_003744.5) | Nonsense Mutation (SNP) | VAF 50/108 reads (46%) | catalogued as COSV100679194, COSV100680020; called by muse, mutect2, varscan2
- NUP88 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV99851968; called by muse, mutect2, varscan2
- OR51B4 | c.169A>G p.M57V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs758320996, COSV100972031; called by muse, mutect2, varscan2
- OR5T2 | c.910A>T p.S304C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100507068; called by muse, mutect2, varscan2
- OR6M1 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV100484178; called by muse, mutect2, varscan2
- OR8G5 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100422656; called by muse, mutect2, varscan2
- PABPC5 | c.904G>C p.V302L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100442674; called by muse, mutect2, varscan2
- PCSK7 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs760741031, COSV56120071, COSV56120206; called by muse, mutect2, varscan2
- PDCD11 | c.656A>T p.K219I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100874414; called by muse, mutect2, varscan2
- PDE4DIP | c.3008A>C p.Q1003P | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as rs139542367, COSV100521676; called by muse, mutect2, varscan2
- PES1 | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100073320; called by muse, mutect2, varscan2
- PKNOX2 | c.893A>T p.H298L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.291); catalogued as COSV100021821; called by muse, mutect2, varscan2
- PKP2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs1274616448, COSV99298457; called by muse, mutect2, varscan2
- PLCG1 | c.3659T>G p.L1220R (on ENST00000373271 / NM_182811.2; = p.L1221R on NM_002660.3) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV99719258; called by muse, mutect2, varscan2
- PPM1H | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99956499; called by muse, mutect2, varscan2
- PPP1R21 | c.719A>C p.N240T | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99682577; called by muse, mutect2, varscan2
- PPP6R1 | c.2248C>G p.Q750E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100497686; called by muse, mutect2, varscan2
- PRAMEF4 | c.1094T>G p.I365R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.144); catalogued as COSV99340197; called by muse, mutect2, varscan2
- PRG3 | c.14T>A p.L5* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as rs144542413; called by muse, mutect2, varscan2
- PROSER3 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99994762; called by muse, mutect2, varscan2
- PSME3 | c.262A>T p.R88W | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV53200659, COSV99513800; called by muse, mutect2, varscan2
- PSTPIP1 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 114/329 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99143959; called by muse, mutect2, varscan2
- PTH2R | c.1210T>A p.F404I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99782864; called by muse, mutect2
- RAB11FIP4 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs749890166, COSV100365752; called by muse, mutect2, varscan2
- RAD50 | c.2389A>G p.R797G | Missense Mutation (SNP) | VAF 81/225 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99529605; called by muse, mutect2, varscan2
- RIMS1 | c.2863T>C p.S955P | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99330292; called by muse, mutect2, varscan2
- RLN1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.35); catalogued as COSV99802834; called by muse, mutect2
- RUNX1T1 | c.314C>T p.S105F (on ENST00000265814 / NM_001198628.1; = p.S78F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56136020; called by muse, mutect2, varscan2
- SAMD4A | c.1085C>G p.A362G | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV51878926, COSV99200823; called by muse, mutect2, varscan2
- SCN10A | c.5366A>G p.D1789G | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101479531; called by muse, mutect2, varscan2
- SEMA3E | c.560T>A p.L187* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as COSV100319571; called by muse, mutect2, varscan2
- SETD2 | c.4375_4376insAATGG p.R1459Qfs*26 | Frame Shift Ins (INS) | VAF 20/75 reads (27%) | catalogued as COSV100339974; called by mutect2, pindel, varscan2
- SH3BP5 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV99508000, COSV99508560; called by muse, mutect2, varscan2
- SLC25A32 | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV99884667; called by muse, mutect2
- SMOC2 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.341); catalogued as COSV100635591; called by muse, mutect2, varscan2
- SPINK5 | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99807319; called by muse, mutect2
- SPTBN2 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.17); catalogued as COSV100019205, COSV100020432; called by muse, mutect2
- SPTBN5 | c.8087C>T p.A2696V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs372953121; called by muse, mutect2, varscan2
- ST6GAL1 | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 30/121 reads (25%) | PolyPhen benign (0.159); catalogued as COSV99399594; called by muse, mutect2, varscan2
- STN1 | c.108C>A p.D36E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99830347; called by muse, mutect2, varscan2
- TAB3 | c.1562A>G p.H521R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99916804; called by muse, mutect2, varscan2
- TERF1 | c.1265A>G p.D422G (on ENST00000276603 / NM_017489.3; = p.D402G on NM_003218.4) | Missense Mutation (SNP) | VAF 209/435 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99401413; called by muse, mutect2, varscan2
- TEX10 | c.1251-2A>G p.X417_splice | Splice Site (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100887965; called by muse, mutect2, varscan2
- TLR3 | c.1754T>C p.L585S | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711210; called by muse, mutect2, varscan2
- TLR9 | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645739; called by muse, mutect2, varscan2
- TMC2 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767021450, COSV100727965; called by muse, mutect2, varscan2
- TMC3 | c.2165G>C p.R722T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs982687836, COSV100846019; called by muse, mutect2, varscan2
- TMED9 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 108/205 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.654); catalogued as COSV100215527; called by muse, mutect2, varscan2
- TMEM132A | c.3038G>A p.R1013H (on ENST00000453848 / NM_178031.3; = p.R1014H on NM_017870.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs373138456; called by muse, mutect2, varscan2
- TMPRSS15 | c.1402A>T p.T468S | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99519236; called by muse, mutect2, varscan2
- TNFSF4 | c.125A>C p.Y42S | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV99919511; called by muse, mutect2, varscan2
- TRPM6 | c.3494T>C p.V1165A | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100666946; called by muse, mutect2, varscan2
- UAP1 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99618059; called by muse, mutect2, varscan2
- UBE2D2 | c.223C>A p.H75N | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99551494; called by muse, mutect2, varscan2
- UBE2D2 | c.224A>T p.H75L | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99551272, COSV99551495; called by muse, mutect2, varscan2
- UCK2 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.854); catalogued as COSV100902815, COSV100903044; called by muse, mutect2, varscan2
- UTP20 | c.6619C>G p.L2207V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55385969, COSV99882504; called by muse, mutect2, varscan2
- VCPIP1 | c.3131G>A p.R1044K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.448); catalogued as COSV100125779; called by muse, mutect2, varscan2
- VPS13B | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663509, COSV62018021; called by muse, mutect2
- VPS13B | c.11222G>A p.R3741Q | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749073153, COSV100663510; called by muse, mutect2, varscan2
- VPS41 | c.2103A>C p.L701F | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV100054324; called by muse, mutect2, varscan2
- WDFY3 | c.4231G>C p.A1411P | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV99885558; called by muse, mutect2, varscan2
- WDR62 | c.2951A>T p.K984M | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV99544184; called by muse, mutect2, varscan2
- WNT11 | c.529A>T p.K177* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100490452; called by muse, mutect2, varscan2
- ZBTB18 | c.265T>C p.F89L | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.161); catalogued as COSV100700226; called by muse, mutect2, varscan2
- ZBTB37 | c.159C>G p.S53R | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100774648; called by muse, mutect2, varscan2
- ZC3H13 | c.3811A>T p.R1271* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99668874; called by muse, mutect2, varscan2
- ZCCHC2 | c.3071A>T p.N1024I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV99502670; called by muse, mutect2, varscan2
- ZNF366 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100574467; called by muse, mutect2, varscan2
- ZNF451 | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1233679294, COSV100674996, COSV100675101; called by muse, mutect2, varscan2
- ZNF526 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV99725455; called by muse, mutect2, varscan2
- ZNF585B | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV100459634; called by muse, mutect2, varscan2
- AKR1C8P | c.126A>C p.K42N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6277_6282del p.S2093_M2094del | In Frame Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel
- KIAA2026 | c.1744dup p.T582Nfs*2 | Frame Shift Ins (INS) | VAF 21/58 reads (36%) | called by mutect2, varscan2
- MAML2 | c.3192_3193del p.Q1064Hfs*37 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- NBPF9 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2
- NTRK3 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PNN | c.1554_1559del p.E519_Q520del | In Frame Del (DEL) | VAF 21/102 reads (21%) | called by mutect2, pindel, varscan2
- RYR3 | c.725_728del p.N242Ifs*29 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- SIK2 | c.1510_1533delinsCTTTA p.M504Lfs*2 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | called by pindel, varscan2*
- TPTE | c.969T>G p.N323K (on ENST00000618007 / NM_199261.4; = p.N305K on NM_199259.4) | Missense Mutation (SNP) | VAF 69/1000 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.03); called by muse, mutect2
- ZCCHC2 | c.1225_1238del p.T409Hfs*19 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- ACTL6B | c.516C>T p.T172= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs773998945, COSV99355745; called by muse, mutect2, varscan2
- ADAM18 | c.1945A>C p.R649= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV99696071; called by muse, mutect2, varscan2
- AGBL1 | c.2847A>G p.A949= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV101224187; called by muse, mutect2, varscan2
- ASB5 | c.117T>C p.S39= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV99642093; called by muse, mutect2
- ATCAY | c.441C>T p.S147= | Silent (SNP) | VAF 34/225 reads (15%) | catalogued as rs771736539, COSV56654170; called by muse, mutect2, varscan2
- BCL2L12 | c.552G>A p.Q184= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- CD7 | c.453C>A p.A151= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV99486375; called by muse, mutect2, varscan2
- DCLK1 | c.1644T>C p.C548= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99712939; called by muse, mutect2, varscan2
- DNAH7 | c.11487T>C p.N3829= | Silent (SNP) | VAF 43/296 reads (15%) | catalogued as COSV100417454; called by muse, mutect2, varscan2
- GPR183 | c.1026T>C p.N342= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV100854397; called by muse, mutect2, varscan2
- GPSM3 | c.12G>A p.E4= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV66680026; called by muse, mutect2, varscan2
- GUCY2D | c.180C>A p.G60= | Silent (SNP) | VAF 195/1006 reads (19%) | catalogued as COSV99644263; called by muse, mutect2, varscan2
- HADHB | c.738G>A p.L246= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100502168; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.963T>C p.F321= (on ENST00000354667 / NM_031243.3; = p.F309= on NM_002137.4) | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as rs774142726, COSV100668447; called by muse, mutect2, varscan2
- HSF2BP | c.136C>T p.L46= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs1459284825, COSV99375750; called by muse, mutect2, varscan2
- IGLV4-69 | c.219T>C p.D73= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as rs1385602565; called by muse, mutect2, varscan2
- ITGA8 | c.2952G>A p.Q984= | Silent (SNP) | VAF 29/172 reads (17%) | catalogued as COSV100959713; called by muse, mutect2, varscan2
- KIF25 | c.705A>T p.G235= | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as COSV100596488; called by muse, varscan2
- KIRREL1 | c.1329G>T p.V443= | Silent (SNP) | VAF 72/139 reads (52%) | catalogued as COSV100780101; called by muse, mutect2, varscan2
- LRRTM2 | c.1143T>C p.Y381= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs757948391, COSV99217879; called by muse, mutect2, varscan2
- MAB21L1 | c.552T>A p.A184= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs781359364, COSV100083985; called by muse, mutect2, varscan2
- MRM3 | c.1104G>A p.Q368= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV100444445; called by muse, mutect2
- MRPL32 | c.18G>A p.L6= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as rs113789800, COSV56237538, COSV99786003; called by muse, mutect2, varscan2
- MUC5B | c.13074G>A p.E4358= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV101500741; called by muse, mutect2, varscan2
- MYO6 | c.2862G>A p.R954= | Silent (SNP) | VAF 85/565 reads (15%) | catalogued as COSV100889416; called by muse, mutect2, varscan2
- N4BP3 | c.453G>T p.T151= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs374439291; called by muse, mutect2, varscan2
- NIPBL | c.2886G>A p.K962= | Silent (SNP) | VAF 268/1376 reads (19%) | catalogued as COSV99242558; called by muse, mutect2, varscan2
- NRAP | c.3327C>T p.H1109= (on ENST00000359988 / NM_001322945.2; = p.H1074= on NM_006175.4) | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as rs759338722, COSV100748594; called by muse, mutect2, varscan2
- OR8K1 | c.816T>C p.H272= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99687533; called by muse, mutect2, varscan2
- OR8U1 | c.87G>A p.V29= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100164118; called by muse, mutect2, varscan2
- OR9Q1 | c.81C>T p.L27= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100110508; called by muse, mutect2, varscan2
- ORC5 | c.1089A>G p.L363= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV99857375; called by muse, mutect2, varscan2
- PBX1 | c.711A>G p.R237= | Silent (SNP) | VAF 44/289 reads (15%) | catalogued as COSV100905271; called by muse, mutect2, varscan2
- PCDHGB7 | c.237G>T p.A79= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV99546437; called by muse, mutect2, varscan2
- PEX13 | c.369A>G p.E123= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs1384058871, COSV99693018; called by muse, mutect2, varscan2
- POU1F1 | c.234T>C p.L78= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV100622780; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1389A>G p.Q463= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as rs149874983, COSV100741450; called by muse, mutect2, varscan2
- RANBP2 | c.7443T>C p.D2481= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV99313209; called by muse, mutect2, varscan2
- REG3G | c.357A>C p.G119= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV99709695; called by muse, mutect2, varscan2
- RFX5 | c.1431G>A p.G477= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV99303306; called by muse, mutect2, varscan2
- RTP5 | c.975G>A p.V325= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1242139016, COSV100574804; called by muse, mutect2, varscan2
- RUNX1T1 | c.9T>A p.S3= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV56152794; called by muse, mutect2, varscan2
- SCN2A | c.4752T>C p.S1584= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as COSV99333398; called by muse, mutect2
- SERTAD4 | c.312A>G p.E104= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as COSV100882664; called by muse, mutect2, varscan2
- SLC4A3 | c.3372T>C p.G1124= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV99813195; called by muse, mutect2
- SLIT2 | c.3411C>T p.I1137= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs1259582147, COSV56567457; called by muse, mutect2, varscan2
- SOX6 | c.1167A>G p.P389= (on ENST00000528429 / NM_001145819.2; = p.P348= on NM_017508.3) | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs774229287, COSV100323194; called by muse, mutect2, varscan2
- TBC1D8 | c.1581A>G p.S527= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100964637; called by muse, mutect2, varscan2
- TBX4 | c.1239T>C p.P413= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV99540672; called by muse, mutect2, varscan2
- TOR1AIP2 | c.831A>T p.G277= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100857529; called by muse, mutect2, varscan2
- TRIM58 | c.1119C>T p.T373= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as rs759619059, COSV100825282; called by muse, mutect2, varscan2
- UBE2E1 | c.581A>G p.*194= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as COSV100135560; called by muse, mutect2, varscan2
- UBTD2 | c.516C>T p.D172= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as COSV101196384; called by muse, mutect2
- UHRF1BP1 | c.3642C>T p.A1214= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs1371870477, COSV99512452; called by muse, mutect2, varscan2
- WASHC5 | c.1198C>T p.L400= | Silent (SNP) | VAF 30/265 reads (11%) | catalogued as COSV100573054; called by muse, mutect2, varscan2
- XPO5 | c.3087A>G p.L1029= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99541399; called by muse, mutect2, varscan2
- ZAN | c.234C>T p.P78= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs1009306334, COSV61809291; called by muse, mutect2, varscan2
- ZFHX3 | c.2355T>C p.N785= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1320473293, COSV99214570; called by muse, varscan2
- LINC02694 | n.288A>C | RNA (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100601943; called by muse, mutect2, varscan2
- SSPOP | n.2731G>A | RNA (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100022981; called by muse, mutect2, varscan2
- TENM4 | c.-321+38461A>G | Intron (SNP) | VAF 12/47 reads (26%) | catalogued as rs1022837721, COSV99578997; called by muse, mutect2, varscan2
